CCDI case PBBJBJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b62c4d1e-bf6b-4dca-a497-2f69a311f4b0

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 20.0 years (7,319 days).

Biospecimens (3 samples)
- Sample 0DAN5X: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DAN63: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DAN6O: Tissue type: Tumor; Specimen type: Solid Tissue.
